CCDI case PBCHHF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/4dc3ff1c-8bb7-4669-9d58-06c9c882e9fb

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Brain stem; Age at diagnosis: 17.6 years (6,436 days).

Biospecimens (3 samples)
- Sample 0DSG1V: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSG21: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSG2I: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
